Surgical pathology report (de-identified scan), TCGA case TCGA-36-2539, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site BC Cancer Agency, specimen TCGA-36-2539-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

**THIS REPORT REPLACES ALL PREVIOUS FINAL REPORTS OF THIS SURGICAL
NUMBER**

TCGA - 36 - 2539

Case Number:

Collect Date:

Receive Date:

Date Reported:

Patient's Name:

MRN:

PHN:

DOB/Gender:

Ordering
Physician:

Addendum Diagnosis

Addendum Diagnosis:

Omentectomy specimen showing high-grade metastatic carcinoma, consistent with metastatic high-grade serous carcinoma (please see Addendum Comment).

Addendum Comment:

The tumor, as noted in the original pathology report, consists of a very high-grade epithelial malignancy with a high mitotic rate. The immunophenotype of the tumor cells (positive for estrogen receptor and WT-1, while negative for progesterone receptor, HER2, and gross cystic disease fluid protein) is most in keeping with this being a high-grade serous carcinoma. It is noted that the patient had an estrogen receptor negative invasive ductal carcinoma in the past and, more recently, an estrogen receptor positive

[page 2 of 3]
invasive lobular carcinoma. This estrogen receptor positive tumor does not show features of lobular carcinoma (uniform cytology). The ER positivity and WT-1 positivity, together with the gross cystic disease fluid protein negativity are against this being metastasis from this patient's previously diagnosed ER negative ductal carcinoma. Thus, although there is some uncertainty with assignment of primary site in this case, I believe the findings are most consistent with this being omental involvement by high-grade serous carcinoma.

In summary, the findings in this case are most suggestive of this being high-grade serous carcinoma, metastatic to the omentum.

End of Addendum Diagnosis

Final Diagnosis:

Omentum, resection specimen:

High-grade malignant tumour extensively invading the omentum with extensive lymphatic spread, (please see Comment).

Final Diagnosis Comment:

The tumor is growing in solid sheets of cells which in areas show nesting and have the appearance of an invasive lobular carcinoma. The mitotic rate is high. Necrosis present and focal areas show bizarre very high grade tumour cells. I favour that this represents metastasis from the previous breast carcinoma.

Immunohistochemical stains for estrogen receptors are strongly positive in about 50% of the tumour cells. PR, HER2/neu & gross cystic disease fluid protein are negative. This profile is consistent with origin from the lobular breast carcinoma, which showed the same staining profile.

[page 3 of 3]
[REDACTED]

Omental cake Bx poorly diff'd adeno Ca Rx taxotere
?Met breast vs primary peritoneal small
Not

Specimens Received:

A: omentum

Gross Description:

The specimen is received in a single container labelled with the patient's demographics and OMENTUM. It consists of an apron of great omentum measuring 29 x 10 x 2 cm. The omentum is distorted by a rubbery nodule measuring 15 x 6 x 3 cm. A cross-section of the nodule shows a tan-white fibrous structure. Representative sections are submitted in A1-A5.

Source: NCI Genomic Data Commons file 7801638b-cb20-46a6-8eaa-c64933b58cf3 (TCGA-36-2539.C388F1D4-53DD-4E8B-BC68-DED38C816530.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).